CGCI case HTMCP-03-06-02364 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/00bd58bd-223d-433e-b60a-5bf355f342b1

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: hispanic or latino; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 56.1 years (20,485 days); Year of diagnosis: 2016; Method of diagnosis: Biopsy; AJCC clinical T: T1b2; AJCC clinical N: NX; AJCC clinical M: MX; FIGO stage: Stage IB2; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 0 days.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: -9 days; Disease response: With Tumor.
- Days to follow up: 0 days; Karnofsky performance status: 90; ECOG performance status: 1.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day 0: Weight: 72 kg; Height: 157.2 cm; BMI: 29.1; Hormonal contraceptive use: Never Used; Hysterectomy type: Not Performed; Menopause status: Postmenopausal; Pregnant at diagnosis: No.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02364-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02364-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02364-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Weight kg at diagnosis: 72 kg; History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 7; Total pregnancy count: 7; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Squamous Cell Carcinoma, Non-Keratinizing; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lymph nodes examined: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: HIV status: Negative.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet02_20191105.xlsx (sheet validation DNAs), for sample HTMCP-03-06-02364-01A-01D-10409:
- % tumour top: 75
- % tumour bottom: 60

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet02_20191105.xlsx (sheet validation DNAs), for sample HTMCP-03-06-02364-10A-01D-10409:
- % tumour top: 0
- % tumour bottom: 0

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet_20191105.xlsx, for sample HTMCP-03-06-02364-01A-02D-10409:
- % tumour top: 75
- % tumour bottom: 60
